Somatic mutation profile of tumor specimen HCM-CSHL-0666-C24-31A (aliquot HCM-CSHL-0666-C24-31A-11D-A85K-36) from HCMI case HCM-CSHL-0666-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.6 years (25,775 days).
Specimen HCM-CSHL-0666-C24-31A: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee39ceb5-d42e-4c04-95cb-1789ca8fdc2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0666-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0666-C24-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1dcddb41-306f-4663-b325-d9ac75bc7c9f

The open-access MAF lists 141 somatic variants for this specimen: 95 protein-altering or splice-affecting, 38 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 38, Nonsense Mutation 8, Intron 3, 5'Flank 2, Splice Region 2, 3'Flank 2, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 214/629 reads (34%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- F8 | c.5143C>T p.R1715* | Nonsense Mutation (SNP) | VAF 277/728 reads (38%) | catalogued as rs137852439, CM900094, CM920258, COSV64271015; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 268/608 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218643327, COSV60787034; called by muse, mutect2, varscan2
- ADAMTS18 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 224/507 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs375093710; called by muse, mutect2, varscan2
- APC | c.3631_3632del p.M1211Vfs*5 | Frame Shift Del (DEL) | VAF 197/624 reads (32%) | catalogued as rs1554085190; called by pindel, varscan2
- APCS | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 186/553 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.649); catalogued as COSV54818769; called by muse, mutect2, varscan2
- ATP2B3 | c.2506G>A p.V836I | Missense Mutation (SNP) | VAF 325/838 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1221371446, COSV54841944; called by muse, mutect2, varscan2
- BTK | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 203/909 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.323); catalogued as CD984238, COSV100437511; called by muse, mutect2, varscan2
- CPZ | c.1882G>A p.D628N (on ENST00000360986 / NM_001014447.3; = p.D617N on NM_003652.3) | Missense Mutation (SNP) | VAF 289/796 reads (36%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs751803458, COSV59926477; called by muse, mutect2, varscan2
- CTNND1 | c.2107C>T p.R703C (on ENST00000399050 / NM_001085458.2; = p.R697C on NM_001331.3) | Missense Mutation (SNP) | VAF 156/402 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377391701; called by muse, mutect2, varscan2
- DENND1A | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 220/528 reads (42%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs775924786, COSV101012112, COSV65348181, COSV65348851; called by mutect2, varscan2
- EDN3 | c.664G>A p.A222T (on ENST00000337938 / NM_001302455.2; = p.A208T on NM_207033.3) | Missense Mutation (SNP) | VAF 289/745 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs201352056; called by muse, mutect2, varscan2
- FAT4 | c.8224G>A p.V2742I | Missense Mutation (SNP) | VAF 227/543 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV58676406; called by muse, mutect2, varscan2
- FES | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 249/580 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.326); catalogued as rs145351114; called by muse, mutect2, varscan2
- FLG | c.9931G>C p.D3311H | Missense Mutation (SNP) | VAF 350/803 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100911422; called by muse, mutect2, varscan2
- GLI3 | c.2864C>T p.T955M | Missense Mutation (SNP) | VAF 81/776 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs767298749, COSV67886413; called by muse, varscan2
- GPR183 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 155/367 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as rs1175864360; called by muse, mutect2, varscan2
- ITGAE | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 146/374 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99560030; called by muse, mutect2, varscan2
- KCNB2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 250/596 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV101578769, COSV73052577; called by muse, mutect2, varscan2
- KCNH1 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 149/409 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55087341; called by muse, mutect2, varscan2
- L1CAM | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 351/796 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs782570664, COSV62827452; called by muse, mutect2, varscan2
- LRRK2 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 130/339 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV54147720; called by muse, mutect2, varscan2
- MAN2A1 | c.3088G>C p.E1030Q | Missense Mutation (SNP) | VAF 280/768 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1246072934, COSV54856879; called by muse, mutect2, varscan2
- MDGA2 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 245/635 reads (39%) | catalogued as rs966820214, COSV62092848; called by muse, mutect2, varscan2
- MEI1 | c.2415C>G p.F805L | Missense Mutation (SNP) | VAF 333/756 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV55903097; called by muse, mutect2, varscan2
- MICAL1 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 242/609 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759678163; called by muse, mutect2, varscan2
- MPO | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 173/474 reads (36%) | catalogued as rs181494077, COSV56563853; called by muse, mutect2, varscan2
- MTG2 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 167/434 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754478626; called by muse, mutect2, varscan2
- MTTP | c.1325A>G p.N442S | Missense Mutation (SNP) | VAF 179/427 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs368711749; called by muse, mutect2, varscan2
- NEK4 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 247/676 reads (37%) | catalogued as rs772792374; called by muse, mutect2, varscan2
- NELFCD | c.187C>T p.R63W (on ENST00000602795; = p.R45W on NM_198976.4) | Missense Mutation (SNP) | VAF 186/497 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as rs755253005; called by muse, mutect2, varscan2
- OR10AC1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 373/902 reads (41%) | SIFT deleterious, low confidence (0.01); catalogued as rs1456382183; called by muse, mutect2, varscan2
- OR2A14 | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 166/479 reads (35%) | catalogued as rs1240904773; called by muse, mutect2, varscan2
- OR51I2 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 211/462 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs181429737; called by muse, mutect2, varscan2
- PAPSS2 | c.27G>C p.T9= | Splice Region (SNP) | VAF 286/654 reads (44%) | catalogued as rs759955222; called by muse, varscan2
- PAX5 | c.620C>A p.P207Q | Missense Mutation (SNP) | VAF 66/542 reads (12%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.993); catalogued as CM142527; called by muse, mutect2, varscan2
- PCDHGA1 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 86/1199 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs373798096; called by muse, mutect2
- PCDHGB7 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 42/1088 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); catalogued as COSV53976596; called by muse, mutect2
- PHLDA1 | c.751T>G p.Y251D | Missense Mutation (SNP) | VAF 283/660 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs747810433, COSV56997397; called by muse, varscan2
- PLEC | c.1550G>A p.R517Q (on ENST00000322810 / NM_201380.4; = p.R407Q on NM_000445.5) | Missense Mutation (SNP) | VAF 241/532 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1410648446; called by muse, mutect2, varscan2
- POLR3C | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 174/430 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1364112287; called by muse, mutect2, varscan2
- SHB | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 278/656 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs985158965; called by muse, mutect2, varscan2
- SLC16A6 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 150/402 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.71); catalogued as rs373369380; called by muse, mutect2, varscan2
- SLC38A4 | c.1446G>T p.G482= | Splice Region (SNP) | VAF 98/264 reads (37%) | catalogued as COSV56970043; called by muse, mutect2, varscan2
- SOX11 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 255/599 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100431212; called by muse, mutect2, varscan2
- SV2C | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 280/719 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139844012, COSV59214450; called by muse, mutect2, varscan2
- SYT16 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 156/390 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs201271787; called by muse, mutect2, varscan2
- TMEM198 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 306/734 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs749142074; called by muse, mutect2, varscan2
- TRIM46 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 175/429 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as rs376400786; called by muse, mutect2, varscan2
- TRPV4 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 227/557 reads (41%) | catalogued as rs1237174071; called by muse, mutect2, varscan2
- TTN | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 283/710 reads (40%) | PolyPhen benign (0.177); catalogued as rs200052202, COSV100618606, COSV59983925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 57/692 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs1311321599, COSV67139341; called by muse, mutect2
- UNC13C | c.3433G>A p.A1145T | Missense Mutation (SNP) | VAF 49/404 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as rs777249610; called by muse, mutect2, varscan2
- USH2A | c.5330G>C p.R1777P | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.65); catalogued as COSV56422675; called by muse, mutect2
- XIRP1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 265/624 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781005341, COSV100453757; called by muse, mutect2, varscan2
- ABCA12 | c.5885G>A p.G1962D (on ENST00000272895 / NM_173076.3; = p.G1644D on NM_015657.3) | Missense Mutation (SNP) | VAF 216/560 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ADAMTS3 | c.2971G>T p.V991F | Missense Mutation (SNP) | VAF 227/544 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ADORA2A | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 347/767 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- ADRA1A | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 26/874 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2
- AKT3 | c.9T>A p.D3E | Missense Mutation (SNP) | VAF 268/682 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALDH7A1 | c.676A>T p.I226F | Missense Mutation (SNP) | VAF 16/498 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2
- ARHGAP29 | c.2438C>G p.S813* | Nonsense Mutation (SNP) | VAF 139/365 reads (38%) | called by muse, mutect2, varscan2
- ATP7A | c.2648A>G p.K883R | Missense Mutation (SNP) | VAF 263/611 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- BMPR1A | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 193/265 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC60 | c.1148G>A p.C383Y | Missense Mutation (SNP) | VAF 168/456 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- CCNB3 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 195/484 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CMYA5 | c.3311C>G p.S1104C | Missense Mutation (SNP) | VAF 246/592 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- DMD | c.1590A>T p.E530D | Missense Mutation (SNP) | VAF 195/500 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ETV5 | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 212/572 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GRM1 | c.2464A>T p.S822C | Missense Mutation (SNP) | VAF 164/657 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEATR1 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 223/550 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPD | c.589A>T p.K197* | Nonsense Mutation (SNP) | VAF 16/540 reads (3%) | called by muse, mutect2
- HYAL4 | c.1326A>C p.E442D | Missense Mutation (SNP) | VAF 245/663 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- JARID2 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 289/747 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- KDM2B | c.2663G>A p.R888H | Missense Mutation (SNP) | VAF 367/813 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL4 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 234/527 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- MYO18A | c.3162G>T p.W1054C | Missense Mutation (SNP) | VAF 245/549 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MZT2B | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 341/800 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP1 | c.1094T>C p.F365S | Missense Mutation (SNP) | VAF 313/729 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NOVA2 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- OGT | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 167/387 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- OR8I2 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 46/602 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- PTBP2 | c.209A>G p.H70R (on ENST00000426398 / NM_001300986.2; = p.H62R on NM_021190.4) | Missense Mutation (SNP) | VAF 172/478 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- RPN1 | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 46/682 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- SH3D19 | c.871A>T p.T291S | Missense Mutation (SNP) | VAF 179/467 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNTG1 | c.771A>C p.Q257H | Missense Mutation (SNP) | VAF 270/565 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SPAG16 | c.598A>C p.K200Q | Missense Mutation (SNP) | VAF 172/511 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM267 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 235/590 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIP12 | c.1389G>T p.Q463H | Missense Mutation (SNP) | VAF 267/648 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TRMT11 | c.462T>G p.D154E | Missense Mutation (SNP) | VAF 198/483 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TXNRD2 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 182/484 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UBTF | c.6C>G p.N2K | Missense Mutation (SNP) | VAF 24/826 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VARS1 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 282/700 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB2 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 242/554 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZNF835 | c.450C>A p.S150R | Missense Mutation (SNP) | VAF 291/760 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ACSL1 | c.1515G>A p.E505= | Silent (SNP) | VAF 211/515 reads (41%) | catalogued as rs913749377; called by muse, mutect2, varscan2
- BVES | c.480T>G p.T160= | Silent (SNP) | VAF 254/673 reads (38%) | catalogued as COSV58947014; called by muse, mutect2, varscan2
- C4orf54 | c.2343G>A p.S781= | Silent (SNP) | VAF 330/767 reads (43%) | catalogued as rs973846472; called by muse, mutect2, varscan2
- DNAH3 | c.11412C>T p.N3804= | Silent (SNP) | VAF 266/680 reads (39%) | catalogued as rs776613491, COSV54511411; called by muse, mutect2, varscan2
- EFEMP1 | c.75G>A p.T25= | Silent (SNP) | VAF 144/381 reads (38%) | catalogued as COSV62616885; called by muse, mutect2
- EPHA6 | c.816T>G p.P272= | Silent (SNP) | VAF 249/609 reads (41%) | called by muse, mutect2, varscan2
- F8 | c.2934A>C p.S978= | Silent (SNP) | VAF 263/674 reads (39%) | called by muse, mutect2, varscan2
- FAAP100 | c.2529G>A p.E843= | Silent (SNP) | VAF 219/517 reads (42%) | called by muse, mutect2, varscan2
- FAT2 | c.9690C>T p.D3230= | Silent (SNP) | VAF 304/851 reads (36%) | catalogued as rs372290937; called by muse, mutect2, varscan2
- FGD1 | c.1956C>T p.L652= | Silent (SNP) | VAF 220/657 reads (33%) | called by muse, mutect2, varscan2
- FIGNL2 | c.1431C>T p.F477= | Silent (SNP) | VAF 209/503 reads (42%) | called by muse, mutect2, varscan2
- GABBR2 | c.435C>T p.S145= | Silent (SNP) | VAF 220/542 reads (41%) | called by muse, mutect2, varscan2
- HEG1 | c.1902G>A p.P634= | Silent (SNP) | VAF 38/625 reads (6%) | catalogued as rs547330294; called by muse, mutect2
- IGHG3 | c.951G>A p.P317= | Silent (SNP) | VAF 274/717 reads (38%) | catalogued as rs375664186; called by muse, mutect2, varscan2
- KCNH3 | c.1926C>T p.G642= | Silent (SNP) | VAF 226/572 reads (40%) | catalogued as rs1223300697; called by muse, mutect2, varscan2
- KLB | c.2628C>T p.V876= | Silent (SNP) | VAF 352/856 reads (41%) | called by muse, mutect2, varscan2
- KLRF2 | c.510G>A p.R170= | Silent (SNP) | VAF 194/518 reads (37%) | called by muse, mutect2
- MEDAG | c.231C>T p.L77= | Silent (SNP) | VAF 38/827 reads (5%) | catalogued as rs1246929062; called by muse, mutect2
- MZT2B | c.81G>C p.L27= | Silent (SNP) | VAF 336/793 reads (42%) | called by muse, mutect2, varscan2
- NCAM2 | c.726C>A p.I242= | Silent (SNP) | VAF 173/438 reads (39%) | called by muse, mutect2, varscan2
- NFASC | c.3012C>T p.H1004= | Silent (SNP) | VAF 188/473 reads (40%) | catalogued as rs751833388; called by muse, mutect2, varscan2
- NRROS | c.39C>T p.H13= | Silent (SNP) | VAF 226/549 reads (41%) | catalogued as rs189782443; called by muse, mutect2, varscan2
- OBP2B | c.252G>A p.T84= | Silent (SNP) | VAF 206/518 reads (40%) | catalogued as rs201697602; called by muse, mutect2, varscan2
- PCDHB5 | c.1941C>A p.G647= | Silent (SNP) | VAF 434/1153 reads (38%) | called by muse, mutect2, varscan2
- PCDHB5 | c.2250C>T p.Y750= | Silent (SNP) | VAF 25/862 reads (3%) | catalogued as rs374460300, COSV50676756; called by muse, mutect2
- PTPRZ1 | c.2805C>A p.G935= | Silent (SNP) | VAF 253/639 reads (40%) | catalogued as rs779642597; called by muse, mutect2, varscan2
- RABL6 | c.654C>T p.F218= | Silent (SNP) | VAF 64/660 reads (10%) | catalogued as rs568788847; called by muse, mutect2
- RASGRF1 | c.39G>A p.A13= | Silent (SNP) | VAF 154/639 reads (24%) | catalogued as rs1465025356; called by muse, mutect2, varscan2
- RIC8B | c.39C>T p.G13= | Silent (SNP) | VAF 203/576 reads (35%) | catalogued as rs762510072; called by muse, mutect2, varscan2
- SETD1B | c.2397C>T p.A799= | Silent (SNP) | VAF 355/842 reads (42%) | catalogued as rs941817496, COSV99931034; called by muse, mutect2, varscan2
- SLITRK3 | c.1761T>A p.G587= | Silent (SNP) | VAF 241/512 reads (47%) | catalogued as COSV53850683; called by muse, mutect2, varscan2
- SMOX | c.555C>T p.D185= | Silent (SNP) | VAF 53/614 reads (9%) | catalogued as rs777935818, COSV99602893; called by muse, mutect2
- SPTBN2 | c.7119C>T p.D2373= | Silent (SNP) | VAF 168/466 reads (36%) | catalogued as rs1213201129; called by muse, mutect2, varscan2
- SSU72P3 | c.36C>T p.C12= | Silent (SNP) | VAF 142/1239 reads (11%) | catalogued as rs1437236990; called by muse, mutect2, varscan2
- TMTC1 | c.183C>T p.P61= | Silent (SNP) | VAF 32/1073 reads (3%) | catalogued as rs1200724192; called by muse, mutect2
- UBTFL1 | c.285C>T p.N95= | Silent (SNP) | VAF 215/568 reads (38%) | catalogued as rs779661592; called by muse, mutect2, varscan2
- WIZ | c.4542C>G p.S1514= (on ENST00000673675 / NM_001371589.1; = p.S419= on NM_021241.3) | Silent (SNP) | VAF 333/815 reads (41%) | called by muse, mutect2, varscan2
- XKR6 | c.381C>T p.L127= | Silent (SNP) | VAF 157/561 reads (28%) | catalogued as rs1459618941, COSV52007916; called by muse, mutect2, varscan2
- AC244258.1 | n.585T>C | RNA (SNP) | VAF 126/311 reads (41%) | called by muse, mutect2, varscan2
- CPNE5 | chr6:36843017 C>T | 5'Flank (SNP) | VAF 180/483 reads (37%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5892726 C>T | 5'Flank (SNP) | VAF 248/595 reads (42%) | called by muse, mutect2, varscan2
- DNAJC12 | c.158-4458G>A | Intron (SNP) | VAF 191/462 reads (41%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1666C>T | Intron (SNP) | VAF 248/623 reads (40%) | catalogued as rs377263806; called by muse, mutect2, varscan2
- LRGUK | c.1843+7364G>T | Intron (SNP) | VAF 234/544 reads (43%) | called by muse, mutect2, varscan2
- SPANXN4 | chrX:143034677 C>A | 3'Flank (SNP) | VAF 197/494 reads (40%) | catalogued as rs1424408220; called by muse, mutect2, varscan2
- SPANXN4 | chrX:143034678 C>A | 3'Flank (SNP) | VAF 193/487 reads (40%) | called by muse, mutect2, varscan2
